CMI case ASCProject_0201 — CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/c68d853e-2788-4c81-94d9-b3f540da5ac2

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Angiosarcoma: Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Age at diagnosis: 36.1 years (13,183 days).

Biospecimens (2 samples)
- Sample ASCProject_0201_SALIVA: Sample type: DNA; Tissue type: Normal; Specimen type: Saliva; Biospecimen anatomic site: Other.
- Sample ASCProject_0201_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
